Somatic mutation profile of tumor specimen TCGA-XE-AANJ-01A (aliquot TCGA-XE-AANJ-01A-11D-A435-10) from TCGA case TCGA-XE-AANJ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 39.2 years (14,314 days).
Specimen TCGA-XE-AANJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccdabb79-37fe-4bc0-a616-d2d465d76884.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AANJ-10A (Blood Derived Normal), aliquot TCGA-XE-AANJ-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7c724d9-fa06-428d-97f5-0723b23aa789

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.1142G>A p.S381N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.99); catalogued as COSV55463659; called by muse, mutect2, varscan2
- GK3P | c.287C>G p.T96S | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56980008; called by muse, mutect2, varscan2
- ZNF469 | c.7964G>C p.G2655A (on ENST00000437464; = p.G2683A on NM_001367624.2) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.175); catalogued as rs912981227; called by muse, mutect2, varscan2
- DCUN1D1 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIPE | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAG | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- PLCE1 | c.1888C>T p.H630Y | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- STAT1 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- UQCC1 | c.841A>T p.K281* | Nonsense Mutation (SNP) | VAF 28/125 reads (22%) | called by muse, mutect2, varscan2
- ZNF462 | c.3805C>A p.Q1269K | Missense Mutation (SNP) | VAF 56/79 reads (71%) | SIFT tolerated (0.16); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CHST2 | c.705C>T p.S235= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- IL17RA | c.1662G>A p.S554= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs777001954; called by muse, mutect2, varscan2
- PTK7 | c.972C>T p.D324= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs775202927; called by muse, mutect2, varscan2
- RGPD4 | c.4266G>T p.G1422= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
